Somatic mutation profile of tumor specimen TCGA-24-0980-01A (aliquot TCGA-24-0980-01A-01W-0420-08) from TCGA case TCGA-24-0980, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.6 years (19,579 days).
Specimen TCGA-24-0980-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d916fee8-9ce4-4ba8-8056-78de4d2d02a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-0980-10A (Blood Derived Normal), aliquot TCGA-24-0980-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef313fe6-bb8e-461d-be96-1aa4c7507498

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 11, Frame Shift Ins 3, Nonsense Mutation 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD35 | c.818C>G p.P273R | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV62910616, COSV62911200; called by muse, mutect2, varscan2
- APOOL | c.632C>A p.A211E | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.348); catalogued as COSV100920829; called by muse, mutect2
- ATP13A1 | c.2789A>T p.Q930L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs550986141, COSV99179194; called by muse, varscan2
- AURKC | c.508G>C p.E170Q (on ENST00000302804 / NM_001015878.2; = p.E136Q on NM_003160.3) | Missense Mutation (SNP) | VAF 96/148 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57138892; called by muse, mutect2, varscan2
- CAMKK2 | c.1642dup p.R548Pfs*66 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | catalogued as rs774981105; called by pindel, varscan2
- CAP1 | c.469A>G p.M157V | Missense Mutation (SNP) | VAF 265/802 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61223633; called by muse, mutect2, varscan2
- CCDC88B | c.3374C>T p.A1125V | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV57266557; called by muse, mutect2, varscan2
- CCT8L2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs376606608, COSV63463644, COSV63463760; called by muse, mutect2, varscan2
- CD19 | c.165G>T p.E55D | Missense Mutation (SNP) | VAF 85/260 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV61188796; called by muse, mutect2, varscan2
- CHD5 | c.5323G>A p.E1775K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99313452; called by muse, mutect2, varscan2
- CHMP4B | c.211C>A p.R71S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV54136242, COSV99460089; called by muse, mutect2, varscan2
- CLEC4F | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 110/323 reads (34%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.935); catalogued as COSV55479754, COSV55479863; called by muse, mutect2, varscan2
- COL4A5 | c.4396C>T p.R1466C | Missense Mutation (SNP) | VAF 200/1030 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746184634, COSV60359944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A6 | c.296T>A p.V99D | Missense Mutation (SNP) | VAF 202/2052 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57868630; called by muse, mutect2
- EFL1 | c.128A>G p.N43S | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51606405; called by muse, mutect2, varscan2
- FGD5 | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as rs751117347, COSV53244747; called by muse, mutect2, varscan2
- FRMD7 | c.138A>T p.E46D | Missense Mutation (SNP) | VAF 141/2310 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100048933; called by muse, mutect2
- GPX6 | c.601C>G p.Q201E | Missense Mutation (SNP) | VAF 48/540 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV62657774; called by muse, mutect2
- HDAC11 | c.716A>T p.E239V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV55473557; called by muse, mutect2, varscan2
- KRT73 | c.983A>C p.K328T | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59839721; called by muse, mutect2, varscan2
- LRFN1 | c.1364A>G p.Q455R | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV50451889; called by muse, mutect2, varscan2
- MAP4 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 192/506 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV64241068; called by muse, mutect2, varscan2
- NCKAP5L | c.1815dup p.S606Qfs*204 | Frame Shift Ins (INS) | VAF 6/33 reads (18%) | catalogued as rs1160641782; called by mutect2, pindel, varscan2
- NSD1 | c.5027C>A p.A1676D | Missense Mutation (SNP) | VAF 215/582 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61777608; called by muse, mutect2, varscan2
- PCDHA11 | c.1173C>G p.H391Q | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs1554163984, COSV56510714, COSV56557593; called by muse, mutect2, varscan2
- PHLDB2 | c.2804G>A p.C935Y (on ENST00000393925 / NM_001134439.2; = p.C892Y on NM_145753.2) | Missense Mutation (SNP) | VAF 135/339 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67312251; called by muse, mutect2, varscan2
- PRRG1 | c.85A>G p.R29G | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV66157850; called by muse, mutect2, varscan2
- RNF213 | c.15332C>T p.P5111L | Missense Mutation (SNP) | VAF 92/132 reads (70%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs191077627, COSV60399778; called by muse, mutect2, varscan2
- SIDT1 | c.1793A>G p.N598S | Missense Mutation (SNP) | VAF 18/608 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV99333778; called by muse, mutect2
- SLAMF7 | c.596A>T p.N199I | Missense Mutation (SNP) | VAF 20/990 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100833260; called by muse, mutect2
- SLC45A3 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as rs773057305, COSV65655042; called by muse, mutect2, varscan2
- SLFN11 | c.2279G>A p.C760Y | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100390570; called by muse, mutect2
- SPIDR | c.2564G>C p.S855T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.067); catalogued as COSV99854932; called by muse, mutect2
- TP53 | c.498dup p.Q167Tfs*14 | Frame Shift Ins (INS) | VAF 89/175 reads (51%) | catalogued as COSV53753495; called by mutect2, pindel, varscan2
- TTN | c.100955A>T p.K33652I (on ENST00000591111; = p.K26228I on NM_003319.4) | Missense Mutation (SNP) | VAF 155/351 reads (44%) | PolyPhen possibly damaging (0.891); catalogued as COSV60117058; called by muse, mutect2, varscan2
- ZNF426 | c.328T>C p.W110R | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53469524; called by muse, mutect2, varscan2
- ZNF454 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as COSV60768801; called by muse, mutect2, varscan2
- MAPK11 | c.676A>T p.S226C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- MCEMP1 | c.6del p.V3Wfs*82 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, varscan2
- MRC1 | c.3244C>T p.R1082* | Nonsense Mutation (SNP) | VAF 106/357 reads (30%) | called by muse, mutect2, varscan2
- CYB5R3 | c.873G>A p.V291= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99349050, COSV99349281; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.768A>T p.I256= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV50051875; called by muse, mutect2, varscan2
- GBP7 | c.24A>T p.P8= | Silent (SNP) | VAF 109/311 reads (35%) | catalogued as COSV54010131; called by muse, mutect2, varscan2
- OR2A5 | c.303C>A p.T101= | Silent (SNP) | VAF 294/971 reads (30%) | catalogued as rs1563026611, COSV68738820, COSV68738836; called by muse, mutect2, varscan2
- PCDH19 | c.2919C>T p.P973= (on ENST00000373034 / NM_001184880.2; = p.P925= on NM_020766.3) | Silent (SNP) | VAF 550/1344 reads (41%) | catalogued as COSV55264759; called by muse, mutect2, varscan2
- RPP40 | c.102G>A p.Q34= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs764040732, COSV100123951; called by muse, mutect2
- RPS6KL1 | c.1581A>G p.E527= | Silent (SNP) | VAF 137/201 reads (68%) | catalogued as COSV53166535; called by muse, mutect2, varscan2
- SEMA5B | c.2265C>T p.C755= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99531621; called by muse, mutect2, varscan2
- SNTA1 | c.1227G>A p.E409= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV99458679; called by muse, mutect2
- TSHZ2 | c.2010G>A p.L670= | Silent (SNP) | VAF 7/157 reads (4%) | catalogued as COSV100295962; called by muse, mutect2
- USP34 | c.6282T>C p.N2094= | Silent (SNP) | VAF 60/189 reads (32%) | catalogued as COSV68402132; called by muse, mutect2, varscan2
- XIST | n.7539C>T | RNA (SNP) | VAF 38/222 reads (17%) | called by muse, varscan2
